Somatic mutation profile of tumor specimen MP2PRT-PARTYT-TMP1-A (aliquot MP2PRT-PARTYT-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PARTYT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (847 days).
Specimen MP2PRT-PARTYT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db653ff-2df3-4010-ba82-85d1cb0ab51f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTYT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTYT-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2254814-5469-42f4-acff-aca8924a7454

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDLBP | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 57/669 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212191858, COSV60499726; called by muse, mutect2
- PRICKLE3 | c.1667C>T p.S556L | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100889905; called by muse, mutect2
- SLC13A5 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 154/533 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777288165, COSV53422173; called by muse, mutect2, varscan2
- TTN | c.34909G>A p.V11637I (on ENST00000591111; = p.V10710I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/298 reads (30%) | PolyPhen benign (0); catalogued as rs374394719; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DOCK2 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 88/1076 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RICTOR | c.2483T>G p.L828W | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SETD2 | c.4094_4095insCCCAGGG p.S1366Pfs*8 | Frame Shift Ins (INS) | VAF 93/207 reads (45%) | called by mutect2, pindel, varscan2
- MUC12 | c.10254C>A p.G3418= (on ENST00000379442; = p.G3275= on NM_001164462.1) | Silent (SNP) | VAF 254/2434 reads (10%) | called by muse, mutect2, varscan2
